Somatic mutation profile of tumor specimen TCGA-IN-A6RN-01A (aliquot TCGA-IN-A6RN-01A-12D-A33T-08) from TCGA case TCGA-IN-A6RN, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,409 days).
Specimen TCGA-IN-A6RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cba52da-cdfd-4f0c-9a89-111b791927a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RN-10A (Blood Derived Normal), aliquot TCGA-IN-A6RN-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e23b9c8-813d-4b86-b141-71c4bb0a459c

The open-access MAF lists 118 somatic variants for this specimen: 81 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 34, Nonsense Mutation 5, Frame Shift Ins 1, Splice Site 1, RNA 1, Frame Shift Del 1, 3'Flank 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769068305, CM092364, COSV99671125; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.3001G>A p.G1001S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV99711231; called by muse, mutect2, varscan2
- AGAP1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58336874; called by muse, mutect2, varscan2
- ANO7 | c.2074T>A p.W692R (on ENST00000274979; = p.W638R on NM_001370694.2) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99238539; called by muse, mutect2
- ARMH3 | c.103A>T p.T35S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100228916; called by muse, mutect2, varscan2
- ATP7A | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100430938; called by muse, mutect2
- CAMK2G | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99989898; called by muse, mutect2, varscan2
- CDH13 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs762117667, COSV99226768; called by muse, mutect2
- CHD6 | c.4897T>C p.Y1633H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV100951087; called by muse, mutect2, varscan2
- CLIC1 | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV101007497, COSV65383543; called by muse, mutect2, varscan2
- CLK3 | c.1307A>G p.N436S (on ENST00000395066 / NM_001130028.1; = p.N288S on NM_003992.4) | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165972; called by muse, mutect2
- CNOT7 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs1334555593, COSV100246616; called by muse, mutect2, varscan2
- CNTNAP4 | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100271723; called by muse, mutect2, varscan2
- CPXCR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52160939; called by muse, mutect2, varscan2
- DDX25 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.069); catalogued as rs763229155, COSV99699954; called by muse, mutect2, varscan2
- DENND6A | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100231518, COSV60769693; called by muse, mutect2
- DEPDC1B | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99409655; called by muse, mutect2, varscan2
- DMXL1 | c.4294T>A p.L1432I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.291); catalogued as COSV100224144; called by muse, mutect2, varscan2
- DOCK11 | c.5029G>T p.G1677* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99353979; called by muse, mutect2, varscan2
- DPP8 | c.661T>A p.C221S (on ENST00000341861 / NM_001320875.2; = p.C205S on NM_017743.6) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); catalogued as COSV100202401; called by muse, mutect2, varscan2
- DSG3 | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753295246, COSV99934247; called by muse, mutect2
- EHBP1 | c.2464A>G p.R822G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99861070; called by muse, mutect2, varscan2
- ESS2 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV99350936; called by muse, mutect2, varscan2
- FAM209B | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs746274558, COSV100990929, COSV100990967; called by muse, mutect2, varscan2
- FGF13 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100264252; called by muse, mutect2
- FLNB | c.6466C>T p.R2156W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1467700421, COSV99913464; called by muse, mutect2, varscan2
- GBP3 | c.50C>G p.T17S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99352587; called by muse, mutect2, varscan2
- GDF15 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV53250406; called by muse, mutect2, varscan2
- GFPT1 | c.1231G>C p.E411Q (on ENST00000357308 / NM_001244710.2; = p.E393Q on NM_002056.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100622849; called by muse, mutect2
- GORASP2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99304582; called by muse, mutect2, varscan2
- HCCS | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100335739; called by muse, mutect2, varscan2
- HEXD | c.1118G>A p.S373N (on ENST00000327949 / NM_001369487.1; = p.A403T on NM_173620.3) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV60066174; called by muse, mutect2, varscan2
- HIVEP3 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 140/344 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99912861; called by muse, mutect2, varscan2
- L3MBTL1 | c.625G>A p.D209N (on ENST00000418998 / NM_001377303.1; = p.D119N on NM_015478.7) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100917179; called by muse, mutect2
- LARP4B | c.1857C>G p.H619Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100295396, COSV60219977; called by muse, mutect2
- MAGEC1 | c.2894T>A p.L965Q | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99595819; called by muse, mutect2
- MARCHF1 | c.207G>C p.R69S (on ENST00000274056; = p.R52S on NM_017923.4) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV99921280; called by muse, mutect2, varscan2
- MDN1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.236); catalogued as COSV101021426; called by muse, mutect2, varscan2
- MED23 | c.2870G>T p.G957V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100645057; called by muse, mutect2, varscan2
- METTL9 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV63961301; called by muse, mutect2, varscan2
- MOV10L1 | c.1138T>A p.C380S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99433994, COSV99434080; called by muse, mutect2, varscan2
- MUC16 | c.35121T>G p.S11707R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); catalogued as COSV101200094; called by muse, mutect2
- MUC6 | c.6622A>T p.I2208F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV101424634; called by muse, mutect2, varscan2
- MYH4 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99701436; called by muse, mutect2, varscan2
- MYO5A | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV100697729; called by muse, mutect2, varscan2
- NBPF10 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as rs781976415, COSV100745057; called by muse, mutect2, varscan2
- NKAP | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101004238; called by muse, mutect2, varscan2
- OR52B6 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs377549706, COSV61447956; called by muse, mutect2, varscan2
- OR5D13 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV62333673, COSV62335009; called by muse, mutect2, varscan2
- OR8U1 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163934; called by muse, mutect2, varscan2
- PDZRN4 | c.3052G>T p.A1018S (on ENST00000402685 / NM_001164595.2; = p.A760S on NM_013377.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV100114636; called by muse, mutect2, varscan2
- PIK3C2A | c.1448+2T>G p.X483_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99790819; called by muse, mutect2, varscan2
- PKHD1 | c.5225C>T p.T1742M | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.572); catalogued as rs372628568; called by muse, mutect2, varscan2
- PRDM9 | c.389T>A p.L130* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99690552; called by muse, mutect2, varscan2
- PRKD3 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99306250; called by muse, mutect2
- PRRC2A | c.5839C>T p.R1947C | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs569266224, COSV99277140; called by muse, mutect2, varscan2
- PTEN | c.500C>G p.T167S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as CM124578, COSV100910397, COSV64291531, COSV64303272; called by muse, mutect2, varscan2
- PZP | c.4422C>G p.S1474R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV99738085; called by muse, mutect2, varscan2
- RP1L1 | c.6413A>G p.E2138G | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV101223295; called by muse, mutect2, varscan2
- S1PR5 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100330766; called by muse, mutect2, varscan2
- SACS | c.11798G>C p.R3933T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101207488; called by muse, mutect2, varscan2
- SALL1 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99174333; called by muse, mutect2, varscan2
- SLC16A11 | c.482G>A p.R161H (on ENST00000308009; = p.R137H on NM_153357.3) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100338658; called by muse, mutect2
- SPPL2C | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV100234059; called by muse, mutect2, varscan2
- ST3GAL1 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | PolyPhen benign (0.026); catalogued as COSV100172145, COSV60611175; called by muse, mutect2, varscan2
- STAG1 | c.2308A>G p.K770E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as COSV52625025, COSV99365718; called by muse, mutect2, varscan2
- SVEP1 | c.9222C>G p.F3074L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs757692485, COSV99929181; called by muse, mutect2, varscan2
- TEX19 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV100331040; called by muse, mutect2, varscan2
- TPH2 | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 39/191 reads (20%) | catalogued as COSV100422117; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs564537532, COSV99161618; called by muse, mutect2, varscan2
- TTC37 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100706675; called by muse, mutect2, varscan2
- TTLL7 | c.1271A>C p.E424A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99552503; called by muse, mutect2, varscan2
- TUBE1 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100037062; called by muse, mutect2, varscan2
- UBQLNL | c.612G>C p.L204F | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100974511; called by muse, mutect2, varscan2
- UTRN | c.8401G>C p.D2801H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100838605, COSV100838682; called by muse, mutect2, varscan2
- ZNF419 | c.1148G>T p.C383F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99692210; called by muse, mutect2, varscan2
- ZNF92 | c.755C>T p.T252I (on ENST00000328747 / NM_152626.4; = p.T183I on NM_007139.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100165698; called by muse, mutect2, varscan2
- MRPL34 | c.179_190del p.R60_K63del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- STX12 | c.711dup p.Q238Tfs*37 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- SYNE2 | c.19503_19519del p.G6502Afs*39 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- TMEM185A | c.1046C>G p.P349R | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ACTBL2 | c.627T>C p.I209= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs192410719, COSV101379358, COSV70661073; called by muse, mutect2, varscan2
- ATP11B | c.1212G>A p.V404= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV100017822; called by muse, mutect2, varscan2
- BICD1 | c.795C>T p.I265= | Silent (SNP) | VAF 20/273 reads (7%) | catalogued as rs1359681008, COSV99862520; called by muse, mutect2
- COL9A3 | c.1041G>A p.E347= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100673431, COSV59652838; called by muse, mutect2, varscan2
- COLEC12 | c.900C>T p.I300= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as rs781630091, COSV68369979; called by muse, mutect2, varscan2
- CSMD1 | c.825T>A p.T275= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101221408; called by muse, mutect2, varscan2
- CUEDC1 | c.285C>T p.S95= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs368159791; called by muse, mutect2, varscan2
- E4F1 | c.873C>T p.D291= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs543875333, COSV100065563; called by muse, mutect2, varscan2
- EHMT2 | c.315C>T p.G105= | Silent (SNP) | VAF 62/305 reads (20%) | catalogued as COSV100977004; called by muse, mutect2, varscan2
- FAM151A | c.1599C>A p.P533= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs769599087, COSV100156944; called by muse, mutect2, varscan2
- HEYL | c.396G>T p.L132= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100865309; called by muse, mutect2, varscan2
- HHIPL2 | c.609C>T p.G203= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100596905; called by muse, mutect2, varscan2
- IFNB1 | c.351C>T p.N117= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as COSV101207810; called by muse, mutect2, varscan2
- MAGEC1 | c.2892C>T p.S964= | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as COSV53568562, COSV99595818; called by muse, mutect2
- MYO15A | c.6645G>A p.A2215= | Silent (SNP) | VAF 90/184 reads (49%) | catalogued as rs770120780, COSV52752731; called by muse, mutect2, varscan2
- NES | c.2139T>A p.S713= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100957883; called by muse, mutect2, varscan2
- NEU4 | c.567G>A p.K189= (on ENST00000391969 / NM_001167602.3; = p.K201= on NM_080741.4) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100372054; called by muse, mutect2, varscan2
- NRXN1 | c.447G>A p.V149= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV101277652; called by muse, mutect2, varscan2
- P4HB | c.594C>G p.L198= | Silent (SNP) | VAF 83/314 reads (26%) | catalogued as COSV100515850; called by muse, mutect2, varscan2
- PACSIN3 | c.279G>C p.A93= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100096388; called by muse, mutect2, varscan2
- PCDH9 | c.1213A>C p.R405= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV100121235; called by muse, mutect2, varscan2
- PHF12 | c.2310G>A p.P770= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs751868565, COSV99255836; called by muse, mutect2, varscan2
- PXDNL | c.3729A>C p.A1243= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100684106; called by muse, mutect2, varscan2
- SEC24C | c.984C>T p.S328= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as rs765470662, COSV100226883; called by muse, mutect2, varscan2
- SELPLG | c.1047C>T p.G349= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99947473; called by muse, mutect2, varscan2
- SPATA17 | c.201A>G p.R67= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100861168; called by muse, mutect2, varscan2
- SREBF2 | c.2391G>A p.A797= | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as rs1197457902, COSV100761435; called by muse, mutect2
- TCEA3 | c.552G>A p.G184= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV101508321; called by muse, mutect2, varscan2
- TNRC18 | c.7365G>T p.G2455= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100078888; called by muse, mutect2, varscan2
- TRIM49 | c.1005T>A p.T335= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs769177777, COSV100316106; called by muse, mutect2, varscan2
- TRPC4 | c.192T>C p.N64= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV100157001; called by muse, mutect2, varscan2
- UHRF1 | c.2097G>A p.A699= (on ENST00000612630 / NM_001290050.1; = p.A712= on NM_013282.4) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99503439; called by muse, mutect2, varscan2
- ZNF417 | c.723G>C p.V241= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100364270; called by mutect2, varscan2
- ZNF670 | c.258G>A p.Q86= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV100829213; called by muse, mutect2, varscan2
- AC024940.1 | n.4075C>G | RNA (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- PI3 | c.-2C>G | 5'UTR (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99714195; called by muse, mutect2, varscan2
- TBX2 | chr17:61412635 G>T | 3'Flank (SNP) | VAF 5/17 reads (29%) | catalogued as rs1462734849; called by muse, mutect2, varscan2
